Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70N, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70N-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology	Final Results
--------------------	---------------

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS: Adrenal mass, left (adrenalectomy): Pheochromocytoma, tumor not seen at inked surface, see note.

NOTE: Immunohistochemical staining with NFTP highlights patchy ganglion cells. Areas of micronodular hyperplasia are seen in the cortex. This case was reviewed by _____ who concurs with the diagnosis. A preliminary diagnosis was communicated to _____ on _____

CLINICAL INFORMATION: Allocate Order to Protocol: _____ Brief

Clinical History: h/o
left adrenal mass (pheochromocytoma) Specimen

Taken For Protocol: 01
- Yes

PROCEDURE: Pre-Operative Diagnosis: left adrenal mass (pheochromocytoma)
Post-Operative Diagnosis: left adrenal mass (pheochromocytoma)
Operative Findings: s/p large left adrenalectomy

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, LEFT

GROSS DESCRIPTION: Received is a single container labeled with the patient's name, medical record number, and "left pheochromocytoma for permanent and Research" is an 8 x 5 x 4.5 cm tan/brown soft tissue specimen that weighs 108 grams. The specimen is photographed, inked in black and bisected to reveal a nodular tan/brown cut surface, with the largest nodule measuring 4.0 cm in diameter. No clearly demarcated normal adrenal gland is identified; however, a few yellow foci are seen peripheral to the largest nodule. A 2.2 x 1.8 x 1.0 cm central piece from the largest nodule is procured for _____ The procurement was performed by _____ on _____ The specimen is received in Surgical Pathology and is consistent with the above description. Representative sections are submitted in white cassettes labeled _____ for permanent processing.

Gross dictated by _____

No consultants

[page 2 of 2]
Surgical Pathology

Final Results

#

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID:

Do not file in Medical Record

Requested By: I

Source: NCI Genomic Data Commons file 791bb072-3857-4aee-8cc9-a8daacd4c4d2 (TCGA-QR-A70N.E0405A01-35EB-4111-981D-BBB916C1D9A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).